Somatic mutation profile of tumor specimen MMRF_2185_1_BM_CD138pos (aliquot MMRF_2185_1_BM_CD138pos_T1_KHS5U_L12871) from MMRF case MMRF_2185, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.3 years (24,597 days).
Specimen MMRF_2185_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 36d671bb-952d-4b29-90cf-012abd05d014.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2185_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2185_1_PB_CD3pos_C2_KHS5U_L12872; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e53b07c5-0c98-4b41-a089-76702e32abf0

The open-access MAF lists 243 somatic variants for this specimen: 91 protein-altering or splice-affecting, 41 silent, 111 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, 3'UTR 56, Silent 41, Intron 33, 5'UTR 9, Nonsense Mutation 7, 5'Flank 6, RNA 4, 3'Flank 3, Frame Shift Del 3, Splice Region 3, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>C p.G12R | Missense Mutation (SNP) | VAF 37/299 reads (12%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.497); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ARFGEF3 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1328190295; called by muse, mutect2, varscan2
- ATP1A1 | c.3042C>T p.G1014= | Splice Region (SNP) | VAF 63/127 reads (50%) | catalogued as COSV55190117; called by muse, mutect2, varscan2
- BCL2L2 | c.248C>G p.S83C | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV51636833; called by muse, mutect2, varscan2
- C2CD2 | c.1454C>T p.S485L | Missense Mutation (SNP) | VAF 21/188 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs146103479; called by muse, mutect2, varscan2
- CACNA1A | c.2650C>T p.R884W | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as rs1408152396; called by muse, mutect2, varscan2
- CCNB3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.012); catalogued as rs1557214261, COSV52081139; called by muse, mutect2, varscan2
- CD22 | c.2468C>G p.S823* | Nonsense Mutation (SNP) | VAF 12/114 reads (11%) | catalogued as COSV99323438; called by muse, mutect2, varscan2
- COL4A2 | c.2804G>A p.G935E | Missense Mutation (SNP) | VAF 47/99 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64627198; called by muse, mutect2, varscan2
- DNAH5 | c.10547G>A p.R3516K | Missense Mutation (SNP) | VAF 18/188 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV54207318; called by muse, mutect2
- FBXL6 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV57352990, COSV57353112; called by muse, mutect2
- FREM3 | c.2852C>T p.S951L | Missense Mutation (SNP) | VAF 32/213 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.011); catalogued as rs1461407631; called by muse, mutect2, varscan2
- GRID2 | c.2098G>C p.E700Q | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV56253148; called by muse, mutect2, varscan2
- GRM8 | c.448G>A p.V150I | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs780348891, COSV58805362, COSV58831333; called by muse, varscan2
- IFRD2 | c.40G>A p.G14S | Missense Mutation (SNP) | VAF 116/269 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs912069612; called by muse, mutect2
- IGHV2-70 | c.171G>C p.W57C | Missense Mutation (SNP) | VAF 85/125 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs370713802; called by muse, varscan2
- IGLV3-1 | c.314A>C p.Y105S | Missense Mutation (SNP) | VAF 119/140 reads (85%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs185803370; called by muse, mutect2, varscan2
- LYST | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 21/254 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs746531909; called by muse, mutect2
- MUC16 | c.40691G>A p.R13564K | Missense Mutation (SNP) | VAF 17/215 reads (8%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.65); catalogued as COSV66690917; called by muse, mutect2
- ODF3L2 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1048680674, COSV59623650; called by muse, mutect2, varscan2
- PIK3R5 | c.1217G>A p.R406H | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.193); catalogued as rs143224779; called by muse, mutect2, varscan2
- RP1 | c.1451C>T p.S484L | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55112617, COSV99606522; called by muse, mutect2, varscan2
- SCN1B | c.448+3G>A | Splice Region (SNP) | VAF 160/339 reads (47%) | catalogued as COSV99386709; called by muse, mutect2, varscan2
- SLC4A1 | c.449G>A p.R150Q | Missense Mutation (SNP) | VAF 11/130 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.315); catalogued as rs761306530, COSV52263891; called by muse, mutect2
- SLC66A2 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); catalogued as rs1289978997, COSV100673887; called by muse, mutect2, varscan2
- SNRPA | c.510C>G p.I170M | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV54680655; called by muse, mutect2, varscan2
- SPIC | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.383); catalogued as COSV54692224; called by muse, mutect2, varscan2
- SURF4 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.183); catalogued as COSV64312227; called by muse, mutect2, varscan2
- TEKT4 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 14/120 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.331); catalogued as rs1558604078; called by muse, mutect2, varscan2
- TESK1 | c.1060C>T p.R354* | Nonsense Mutation (SNP) | VAF 27/187 reads (14%) | catalogued as rs1216606540; called by muse, mutect2, varscan2
- UQCR10 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 103/225 reads (46%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs374152934, COSV57458811; called by muse, mutect2, varscan2
- ADAMTS4 | c.1064C>T p.S355L | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.224); called by muse, mutect2
- ANKLE1 | c.1373C>A p.S458* (on ENST00000394458; = p.S404* on NM_152363.6) | Nonsense Mutation (SNP) | VAF 40/307 reads (13%) | called by muse, mutect2, varscan2
- ANKZF1 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 32/326 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.172); called by muse, mutect2
- ATXN3 | c.61A>T p.N21Y | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDK1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CECR2 | c.4213C>G p.Q1405E (on ENST00000342247 / NM_001290047.2; = p.Q1221E on NM_001290046.1) | Missense Mutation (SNP) | VAF 10/107 reads (9%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.054); called by muse, mutect2
- CHD1L | c.2038A>G p.N680D | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CMTR2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 14/183 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CNTN5 | c.3067G>C p.V1023L | Missense Mutation (SNP) | VAF 105/249 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, varscan2
- COL7A1 | c.7560A>G p.G2520= | Splice Region (SNP) | VAF 17/93 reads (18%) | called by muse, mutect2, varscan2
- CPT2 | c.690_694del p.S230Rfs*2 | Frame Shift Del (DEL) | VAF 69/162 reads (43%) | called by mutect2, pindel, varscan2
- CRB1 | c.903G>C p.L301F | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.873); called by muse, mutect2
- CRISP2 | c.415C>T p.Q139* | Nonsense Mutation (SNP) | VAF 11/101 reads (11%) | called by muse, mutect2, varscan2
- DCAF15 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 15/147 reads (10%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2
- EHF | c.142C>T p.Q48* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | called by muse, mutect2, varscan2
- EIF5 | c.1103C>T p.A368V | Missense Mutation (SNP) | VAF 43/99 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, mutect2, varscan2
- ESRP2 | c.1629G>A p.M543I (on ENST00000565858 / NM_001365264.1; = p.M533I on NM_024939.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 32/369 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2
- FASN | c.6619G>A p.E2207K | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FGD2 | c.1555G>A p.G519R | Missense Mutation (SNP) | VAF 104/231 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FGFR1OP2 | c.678G>C p.L226F | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- FYCO1 | c.1315G>C p.E439Q | Missense Mutation (SNP) | VAF 45/429 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- GABRR1 | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- GEMIN5 | c.760del p.W254Gfs*9 | Frame Shift Del (DEL) | VAF 78/172 reads (45%) | called by mutect2, varscan2
- GIT2 | c.747A>G p.I249M | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- GLI3 | c.3521C>T p.S1174F | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.352); called by muse, mutect2, varscan2
- GPR26 | c.296C>T p.A99V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- GPR63 | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 114/254 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2, varscan2
- H2AP | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- HTR1E | c.1060G>T p.A354S | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFT140 | c.238T>C p.W80R | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHV1-69D | c.339T>A p.Y113* | Nonsense Mutation (SNP) | VAF 82/93 reads (88%) | called by muse, mutect2, varscan2
- LIFR | c.3273del p.Q1092Rfs*24 | Frame Shift Del (DEL) | VAF 71/492 reads (14%) | called by mutect2, varscan2
- MINDY2 | c.1090C>T p.P364S | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.667); called by muse, mutect2, varscan2
- MYH4 | c.3883C>A p.L1295I | Missense Mutation (SNP) | VAF 27/229 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NLE1 | c.1387G>A p.D463N | Missense Mutation (SNP) | VAF 31/228 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NTN1 | c.1173G>A p.M391I | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.062); called by muse, mutect2
- OR5M1 | c.365G>T p.R122L | Missense Mutation (SNP) | VAF 19/163 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- POC1B-GALNT4 | c.1000G>A p.E334K | Missense Mutation (SNP) | VAF 68/718 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PREB | c.1099A>G p.T367A | Missense Mutation (SNP) | VAF 108/235 reads (46%) | SIFT tolerated (0.66); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRKD2 | c.1648C>G p.Q550E | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PROCR | c.457G>C p.D153H | Missense Mutation (SNP) | VAF 16/127 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SDC1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- SHROOM4 | c.2362C>T p.H788Y | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLC37A1 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 25/141 reads (18%) | called by muse, mutect2, varscan2
- SPTBN2 | c.4801G>A p.E1601K | Missense Mutation (SNP) | VAF 94/229 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- STAG3 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 28/322 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.391); called by muse, mutect2
- TBL1X | c.1058C>G p.T353R | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TCF15 | c.466G>T p.D156Y | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- TM6SF2 | c.1133G>C p.*378Sext*? | Nonstop Mutation (SNP) | VAF 5/80 reads (6%) | called by muse, mutect2
- TMCC3 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 10/218 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); called by muse, mutect2
- UBR4 | c.7197G>T p.K2399N | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- UQCRFS1 | c.718G>A p.G240R | Missense Mutation (SNP) | VAF 87/160 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- USP38 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2
- USPL1 | c.2533C>A p.H845N | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0); called by muse, mutect2, varscan2
- UTF1 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- VPS33B | c.701-1G>C p.X234_splice | Splice Site (SNP) | VAF 23/207 reads (11%) | called by muse, mutect2, varscan2
- ZBTB10 | c.1132C>G p.H378D | Missense Mutation (SNP) | VAF 17/193 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZFP36L1 | c.641C>T p.A214V | Missense Mutation (SNP) | VAF 59/111 reads (53%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ZNF784 | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.033); called by muse, mutect2
- ZSCAN22 | c.784T>A p.Y262N | Missense Mutation (SNP) | VAF 27/225 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ADI1 | c.351C>T p.I117= | Silent (SNP) | VAF 35/240 reads (15%) | catalogued as COSV59377355; called by muse, mutect2, varscan2
- AGTPBP1 | c.1887C>T p.L629= (on ENST00000357081 / NM_001330701.2; = p.L589= on NM_015239.2) | Silent (SNP) | VAF 17/196 reads (9%) | catalogued as rs1484191099; called by muse, mutect2
- ANKRD27 | c.2604A>C p.S868= | Silent (SNP) | VAF 20/52 reads (38%) | called by mutect2, varscan2
- ARC | c.834G>T p.T278= | Silent (SNP) | VAF 26/182 reads (14%) | called by muse, mutect2
- BTBD8 | c.4374C>T p.P1458= (on ENST00000636805 / NM_001376131.1; = p.P945= on NM_015237.4) | Silent (SNP) | VAF 60/145 reads (41%) | called by muse, mutect2, varscan2
- C4BPA | c.1761C>T p.S587= | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs762923928, COSV100891174; called by muse, mutect2, varscan2
- CHPT1 | c.63G>A p.L21= | Silent (SNP) | VAF 16/28 reads (57%) | catalogued as rs749250020; called by muse, mutect2, varscan2
- CLCNKA | c.564C>T p.I188= | Silent (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
- CLEC1A | c.555G>A p.A185= | Silent (SNP) | VAF 63/124 reads (51%) | catalogued as rs141659416; called by muse, mutect2, varscan2
- CNNM4 | c.2277C>T p.L759= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.1158C>T p.F386= | Silent (SNP) | VAF 27/227 reads (12%) | called by muse, mutect2, varscan2
- COLEC11 | c.636C>T p.G212= | Silent (SNP) | VAF 140/348 reads (40%) | catalogued as rs141570591; called by muse, mutect2, varscan2
- DGCR8 | c.1572C>T p.L524= | Silent (SNP) | VAF 16/172 reads (9%) | catalogued as rs1159221629; called by muse, mutect2
- DUS2 | c.141C>A p.L47= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2
- EIF4E2 | c.87G>A p.E29= | Silent (SNP) | VAF 10/242 reads (4%) | called by muse, mutect2
- EMILIN1 | c.96C>T p.Y32= | Silent (SNP) | VAF 85/186 reads (46%) | called by muse, mutect2, varscan2
- ERG | c.1083G>A p.R361= (on ENST00000398919 / NM_001243428.1; = p.R337= on NM_004449.4) | Silent (SNP) | VAF 8/153 reads (5%) | catalogued as COSV55727417; called by muse, mutect2
- FAM32A | c.276C>T p.F92= | Silent (SNP) | VAF 105/236 reads (44%) | called by muse, mutect2, varscan2
- GASK1B | c.774C>A p.L258= | Silent (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- HK2 | c.2328C>G p.L776= | Silent (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- ISCA2 | c.102G>A p.A34= | Silent (SNP) | VAF 33/73 reads (45%) | called by muse, mutect2, varscan2
- ITPKB | c.111G>A p.P37= | Silent (SNP) | VAF 11/119 reads (9%) | catalogued as rs941510330, COSV99684484; called by muse, mutect2
- KLK1 | c.462G>A p.L154= | Silent (SNP) | VAF 141/334 reads (42%) | called by muse, mutect2, varscan2
- LHX8 | c.264C>G p.L88= | Silent (SNP) | VAF 21/131 reads (16%) | called by muse, mutect2, varscan2
- NIN | c.5409G>A p.V1803= (on ENST00000382041 / NM_182946.1; = p.V1090= on NM_016350.4) | Silent (SNP) | VAF 37/348 reads (11%) | called by muse, mutect2, varscan2
- NOS1 | c.279G>A p.V93= | Silent (SNP) | VAF 22/136 reads (16%) | catalogued as rs1158548899; called by muse, mutect2, varscan2
- PDS5A | c.2577A>T p.S859= | Silent (SNP) | VAF 9/249 reads (4%) | called by muse, mutect2
- PGD | c.816G>A p.L272= | Silent (SNP) | VAF 93/203 reads (46%) | called by muse, mutect2, varscan2
- PHF14 | c.2448A>G p.P816= | Silent (SNP) | VAF 85/189 reads (45%) | catalogued as rs1404132767; called by muse, mutect2, varscan2
- PSMF1 | c.6G>A p.A2= | Silent (SNP) | VAF 9/244 reads (4%) | catalogued as rs1473144897, COSV99850550; called by muse, mutect2
- SALL1 | c.3438G>A p.S1146= | Silent (SNP) | VAF 11/95 reads (12%) | catalogued as rs762494276, COSV99173809; called by muse, mutect2, varscan2
- SEMA4B | c.1590G>A p.R530= | Silent (SNP) | VAF 61/115 reads (53%) | catalogued as rs777163451; called by muse, mutect2, varscan2
- SERINC5 | c.147C>T p.L49= | Silent (SNP) | VAF 56/402 reads (14%) | called by muse, mutect2, varscan2
- TAS2R39 | c.933G>A p.L311= | Silent (SNP) | VAF 58/303 reads (19%) | catalogued as rs1333544493, COSV71470850; called by muse, mutect2, varscan2
- THRAP3 | c.1713C>T p.V571= | Silent (SNP) | VAF 6/92 reads (7%) | called by muse, mutect2
- TMPRSS11D | c.828G>C p.V276= | Silent (SNP) | VAF 23/170 reads (14%) | catalogued as COSV52221341, COSV52223952; called by muse, mutect2, varscan2
- TRRAP | c.6006G>A p.Q2002= (on ENST00000359863 / NM_001244580.1; = p.Q1984= on NM_003496.3) | Silent (SNP) | VAF 17/78 reads (22%) | called by muse, mutect2, varscan2
- TSGA13 | c.567G>A p.K189= | Silent (SNP) | VAF 5/62 reads (8%) | catalogued as rs1433425489; called by muse, mutect2
- UBASH3A | c.1059C>T p.F353= | Silent (SNP) | VAF 18/162 reads (11%) | catalogued as rs951528531; called by muse, mutect2, varscan2
- ZNF280B | c.903G>A p.Q301= | Silent (SNP) | VAF 36/272 reads (13%) | called by muse, mutect2, varscan2
- ZNF318 | c.2115C>T p.L705= | Silent (SNP) | VAF 8/124 reads (6%) | called by muse, mutect2
- AC109486.1 | n.149G>A | RNA (SNP) | VAF 64/151 reads (42%) | called by muse, mutect2, varscan2
- ALX3 | c.*392C>T | 3'UTR (SNP) | VAF 77/173 reads (45%) | called by muse, mutect2, varscan2
- ANKH | c.96+171C>G | Intron (SNP) | VAF 20/150 reads (13%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 30/65 reads (46%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- ARMC5 | chr16:31459301 C>T | 5'Flank (SNP) | VAF 48/85 reads (56%) | called by muse, mutect2, varscan2
- ATXN2L | chr16:28823089 C>T | 5'Flank (SNP) | VAF 11/67 reads (16%) | catalogued as COSV57375532; called by muse, mutect2, varscan2
- BAZ1A | c.1607-28del | Intron (DEL) | VAF 20/62 reads (32%) | called by pindel, varscan2
- BBS12 | c.*900G>C | 3'UTR (SNP) | VAF 8/52 reads (15%) | called by muse, mutect2
- BIRC3 | c.*2027G>A | 3'UTR (SNP) | VAF 10/38 reads (26%) | called by muse, mutect2, varscan2
- C17orf75 | c.491+49G>A | Intron (SNP) | VAF 49/131 reads (37%) | catalogued as rs1393439621; called by muse, mutect2, varscan2
- CCNI | c.-119C>T | 5'UTR (SNP) | VAF 80/260 reads (31%) | called by muse, varscan2
- CD48 | c.385+193C>T | Intron (SNP) | VAF 34/356 reads (10%) | catalogued as rs1474923654; called by muse, mutect2
- CDKN2B | c.*321G>C | 3'UTR (SNP) | VAF 110/271 reads (41%) | called by muse, mutect2, varscan2
- CHD6 | c.*1592G>A | 3'UTR (SNP) | VAF 40/102 reads (39%) | called by muse, mutect2, varscan2
- CHRAC1 | c.-29C>T | 5'UTR (SNP) | VAF 42/106 reads (40%) | called by muse, mutect2, varscan2
- DBX2 | c.*999C>T | 3'UTR (SNP) | VAF 7/60 reads (12%) | catalogued as rs1057072066; called by muse, mutect2, varscan2
- DCP2 | c.*1234C>T | 3'UTR (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- DDX3X | c.*2058G>C | 3'UTR (SNP) | VAF 27/108 reads (25%) | called by muse, mutect2, varscan2
- DEAF1 | c.-102C>T | 5'UTR (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- DHRS7 | c.633+18C>T | Intron (SNP) | VAF 15/150 reads (10%) | catalogued as rs1262428881; called by muse, mutect2, varscan2
- DLGAP2 | c.*2733C>T | 3'UTR (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2
- DNAJC17 | c.382-84G>A | Intron (SNP) | VAF 18/205 reads (9%) | catalogued as rs1241864220; called by muse, mutect2
- EEF1A1 | c.-30-108G>C | Intron (SNP) | VAF 102/237 reads (43%) | catalogued as rs767764040; called by muse, mutect2, varscan2
- ELL | c.*89G>C | 3'UTR (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2
- ETFA | c.-6G>A | 5'UTR (SNP) | VAF 9/88 reads (10%) | called by muse, mutect2
- FAM71D | c.160-1563G>C | Intron (SNP) | VAF 10/53 reads (19%) | called by muse, mutect2, varscan2
- FANCC | c.-44G>C | 5'UTR (SNP) | VAF 30/633 reads (5%) | called by muse, mutect2
- FNDC10 | c.*214G>T | 3'UTR (SNP) | VAF 30/72 reads (42%) | called by muse, mutect2, varscan2
- FPGT | c.*1386C>A | 3'UTR (SNP) | VAF 27/65 reads (42%) | called by muse, mutect2, varscan2
- GLCE | c.*529G>C | 3'UTR (SNP) | VAF 16/78 reads (21%) | called by muse, mutect2
- GOLGA8A | c.*2134G>A | 3'UTR (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- HECTD4 | c.2743-410C>T | Intron (SNP) | VAF 9/107 reads (8%) | called by muse, mutect2
- HLX | c.*172T>C | 3'UTR (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- HSPB8 | c.-98A>C | 5'UTR (SNP) | VAF 49/112 reads (44%) | called by muse, mutect2, varscan2
- IER3 | c.*140G>A | 3'UTR (SNP) | VAF 38/72 reads (53%) | called by muse, mutect2, varscan2
- IL17RB | c.747+9C>T | Intron (SNP) | VAF 49/108 reads (45%) | called by muse, mutect2, varscan2
- INPP5F | c.1887-1838C>T | Intron (SNP) | VAF 11/87 reads (13%) | called by muse, mutect2, varscan2
- KCND2 | c.*1566A>G | 3'UTR (SNP) | VAF 40/76 reads (53%) | called by muse, mutect2, varscan2
- KCNK2 | c.*1315C>A | 3'UTR (SNP) | VAF 11/107 reads (10%) | called by muse, mutect2
- KCNS2 | c.*3126C>G | 3'UTR (SNP) | VAF 8/51 reads (16%) | called by muse, mutect2, varscan2
- KIF6 | c.*5661G>A | 3'UTR (SNP) | VAF 50/346 reads (14%) | catalogued as rs1197355391; called by muse, mutect2, varscan2
- KTN1 | c.3439-34G>A | Intron (SNP) | VAF 7/90 reads (8%) | called by muse, mutect2
- LHX3 | c.*846C>G | 3'UTR (SNP) | VAF 12/123 reads (10%) | called by muse, mutect2
- LINC02870 | n.512C>T | RNA (SNP) | VAF 48/125 reads (38%) | catalogued as rs749097459; called by muse, mutect2, varscan2
- LPGAT1 | chr1:211747404 G>A | 3'Flank (SNP) | VAF 9/91 reads (10%) | called by muse, mutect2
- LTB | c.209-63C>G | Intron (SNP) | VAF 54/112 reads (48%) | called by muse, varscan2
- LTB | c.209-88G>A | Intron (SNP) | VAF 65/125 reads (52%) | called by muse, varscan2
- MAP3K20 | c.988-3839G>C | Intron (SNP) | VAF 4/98 reads (4%) | called by muse, mutect2
- MAP4 | c.292+3168C>G | Intron (SNP) | VAF 17/113 reads (15%) | called by muse, mutect2
- MAP9 | c.*3014G>A | 3'UTR (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- MAPK8 | c.*2496G>C | 3'UTR (SNP) | VAF 13/86 reads (15%) | called by muse, mutect2, varscan2
- MATN4 | c.*66C>T | 3'UTR (SNP) | VAF 18/38 reads (47%) | called by muse, mutect2, varscan2
- MBD5 | c.*3216G>C | 3'UTR (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- MCM8 | chr20:5995234 C>T | 3'Flank (SNP) | VAF 11/98 reads (11%) | called by muse, mutect2, varscan2
- MOCS1 | c.*907C>G | 3'UTR (SNP) | VAF 76/447 reads (17%) | called by muse, mutect2, varscan2
- MPRIP | c.2163+3383T>A | Intron (SNP) | VAF 72/138 reads (52%) | called by muse, mutect2, varscan2
- MTERF1 | c.*2168G>A | 3'UTR (SNP) | VAF 52/111 reads (47%) | catalogued as rs1270321163; called by muse, mutect2, varscan2
- MTR | c.*2776_*2778del | 3'UTR (DEL) | VAF 6/48 reads (13%) | catalogued as rs75001053; called by pindel, varscan2
- NEDD4 | c.*2564G>A | 3'UTR (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- NEDD4 | c.*1710G>A | 3'UTR (SNP) | VAF 10/107 reads (9%) | called by muse, varscan2
- NFIB | c.*6163T>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- NHLH2 | c.-8-853C>T | Intron (SNP) | VAF 46/93 reads (49%) | called by muse, mutect2, varscan2
- NSUN3 | c.*10G>A | 3'UTR (SNP) | VAF 21/254 reads (8%) | catalogued as rs765306129; called by muse, mutect2
- PACSIN3 | c.604-40G>A | Intron (SNP) | VAF 42/94 reads (45%) | called by muse, mutect2, varscan2
- PCDHB16 | c.*218G>A | 3'UTR (SNP) | VAF 27/76 reads (36%) | called by muse, mutect2, varscan2
- PELI2 | c.*639G>A | 3'UTR (SNP) | VAF 35/75 reads (47%) | called by muse, mutect2, varscan2
- PEX5L | c.*2536G>A | 3'UTR (SNP) | VAF 27/79 reads (34%) | called by muse, mutect2, varscan2
- PGLYRP2 | c.1641+270C>G | Intron (SNP) | VAF 9/87 reads (10%) | called by muse, mutect2, varscan2
- PHF20L1 | c.930+725G>C | Intron (SNP) | VAF 14/102 reads (14%) | catalogued as COSV55188477; called by muse, mutect2, varscan2
- PKN1 | c.22-875G>A | Intron (SNP) | VAF 6/86 reads (7%) | catalogued as rs1159526946; called by muse, mutect2
- PLEK | c.*1290G>A | 3'UTR (SNP) | VAF 23/119 reads (19%) | catalogued as rs1313080004; called by muse, mutect2, varscan2
- POM121L12 | c.*251G>A | 3'UTR (SNP) | VAF 19/120 reads (16%) | called by muse, mutect2, varscan2
- PSD3 | c.1911-898G>A | Intron (SNP) | VAF 32/75 reads (43%) | catalogued as rs895545787; called by muse, mutect2, varscan2
- PTCH2 | chr1:44820441 G>A | 3'Flank (SNP) | VAF 63/168 reads (38%) | called by muse, mutect2, varscan2
- PYGO1 | c.*543G>T | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- RAB11A | c.*3685C>T | 3'UTR (SNP) | VAF 7/79 reads (9%) | called by muse, mutect2
- RAB26 | c.*344A>T | 3'UTR (SNP) | VAF 142/314 reads (45%) | called by muse, mutect2, varscan2
- RAB40A | c.*100C>T | 3'UTR (SNP) | VAF 54/76 reads (71%) | called by muse, varscan2
- RABL2A | c.*16+133G>A | Intron (SNP) | VAF 195/576 reads (34%) | catalogued as rs1438361534; called by muse, mutect2, varscan2
- RPRM | c.*679G>C | 3'UTR (SNP) | VAF 21/201 reads (10%) | called by muse, mutect2, varscan2
- SALL2 | c.-261G>A | 5'UTR (SNP) | VAF 12/92 reads (13%) | called by mutect2, varscan2
- SBNO2 | c.*75C>T | 3'UTR (SNP) | VAF 5/24 reads (21%) | called by mutect2, varscan2
- SCLT1 | c.*300T>A | 3'UTR (SNP) | VAF 28/57 reads (49%) | called by muse, mutect2, varscan2
- SERF2 | chr15:43792232 C>T | 5'Flank (SNP) | VAF 25/139 reads (18%) | called by muse, mutect2, varscan2
- SMARCAD1 | c.*552G>A | 3'UTR (SNP) | VAF 11/94 reads (12%) | called by muse, mutect2, varscan2
- SMPD4BP | n.655G>A | RNA (SNP) | VAF 67/136 reads (49%) | called by muse, mutect2, varscan2
- SOAT1 | c.*2271G>T | 3'UTR (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- SPEF2 | c.2839+1380G>A | Intron (SNP) | VAF 10/16 reads (63%) | called by muse, mutect2, varscan2
- SPOPL | c.*336G>A | 3'UTR (SNP) | VAF 16/25 reads (64%) | called by muse, mutect2, varscan2
- SRP72 | c.611-68C>A | Intron (SNP) | VAF 5/24 reads (21%) | catalogued as COSV61378179; called by muse, mutect2, varscan2
- SSPOP | n.15422C>T | RNA (SNP) | VAF 11/123 reads (9%) | called by muse, mutect2
- SUFU | c.*3244C>T | 3'UTR (SNP) | VAF 48/107 reads (45%) | called by muse, mutect2, varscan2
- TANGO2 | c.451+136C>A | Intron (SNP) | VAF 27/98 reads (28%) | catalogued as rs1450563782; called by muse, mutect2, varscan2
- THUMPD2 | c.*135G>A | 3'UTR (SNP) | VAF 8/58 reads (14%) | called by muse, mutect2, varscan2
- TLE3 | c.373-694G>A | Intron (SNP) | VAF 8/82 reads (10%) | called by muse, mutect2, varscan2
- TMEM170B | c.*325C>T | 3'UTR (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- TRIM16 | chr17:15683133 G>A | 5'Flank (SNP) | VAF 181/559 reads (32%) | called by muse, mutect2, varscan2
- TRPM3 | c.1154+8396G>A | Intron (SNP) | VAF 34/111 reads (31%) | called by muse, mutect2, varscan2
- TTBK1 | c.*2617C>T | 3'UTR (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- TTC30A | c.*695C>T | 3'UTR (SNP) | VAF 42/115 reads (37%) | called by muse, mutect2
- TTC39B | c.275+17936G>A | Intron (SNP) | VAF 158/392 reads (40%) | called by muse, mutect2, varscan2
- UGCG | c.*269A>T | 3'UTR (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- UTY | c.-154C>T | 5'UTR (SNP) | VAF 20/99 reads (20%) | called by muse, mutect2, varscan2
- WDFY3 | c.2345+23G>A | Intron (SNP) | VAF 9/115 reads (8%) | catalogued as rs774231773; called by muse, mutect2
- WRAP73 | c.222+52G>A | Intron (SNP) | VAF 16/30 reads (53%) | called by muse, varscan2
- XKR9 | c.*889G>A | 3'UTR (SNP) | VAF 18/87 reads (21%) | called by muse, mutect2, varscan2
- YPEL5 | c.-24-25G>A | Intron (SNP) | VAF 86/303 reads (28%) | called by muse, mutect2, varscan2
- ZBTB7B | chr1:155010992 C>T | 5'Flank (SNP) | VAF 29/53 reads (55%) | called by muse, mutect2, varscan2
- ZCCHC10 | c.*1197T>A | 3'UTR (SNP) | VAF 28/161 reads (17%) | called by muse, mutect2, varscan2
- ZNF681 | c.*486A>T | 3'UTR (SNP) | VAF 66/156 reads (42%) | called by muse, mutect2, varscan2
- ZNF683 | chr1:26374410 A>G | 5'Flank (SNP) | VAF 64/146 reads (44%) | called by muse, mutect2, varscan2
